Somatic mutation profile of tumor specimen TCGA-98-A538-01A (aliquot TCGA-98-A538-01A-11D-A25L-08) from TCGA case TCGA-98-A538, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 67.6 years (24,698 days).
Specimen TCGA-98-A538-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c167f13e-4fff-410b-bf41-a9f2edb629ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-98-A538-10A (Blood Derived Normal), aliquot TCGA-98-A538-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/626a036a-fa4c-4941-962f-0126bd8cad87

The open-access MAF lists 715 somatic variants for this specimen: 546 protein-altering or splice-affecting, 149 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 458, Silent 149, Nonsense Mutation 37, Frame Shift Del 19, Splice Site 13, Splice Region 10, Intron 7, RNA 6, Frame Shift Ins 6, 5'UTR 3, 3'UTR 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.407G>T p.C136F | Missense Mutation (SNP) | VAF 54/130 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD110173, CM983501, COSV64288670, COSV64294671; called by muse, mutect2, varscan2
- TP53 | c.993G>T p.Q331H | Missense Mutation (SNP) | VAF 23/66 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs11575996, CS125161, COSV52681350, COSV52690011, COSV52951377, COSV99391417; called by muse, mutect2, varscan2
- AADAC | c.95G>C p.R32T | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV99233338; called by muse, mutect2
- ABCB5 | c.2917G>T p.V973F (on ENST00000404938 / NM_001163941.2; = p.V528F on NM_178559.6) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV99328818; called by muse, mutect2, varscan2
- ABCC1 | c.3688G>T p.V1230L | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV100579871; called by muse, mutect2, varscan2
- ABHD15 | c.804C>G p.C268W | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99975467; called by muse, mutect2, varscan2
- AC090517.4 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); catalogued as COSV99974689; called by muse, mutect2, varscan2
- ACCS | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV99772887; called by muse, mutect2, varscan2
- ACOX1 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1268755550, COSV53138433; called by muse, mutect2, varscan2
- ACTA1 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 36/138 reads (26%) | catalogued as CM041989, COSV100796768, COSV64204258; called by muse, mutect2, varscan2
- ACTA1 | c.252G>T p.M84I | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV100796769, COSV64203786; called by muse, mutect2, varscan2
- ACTA1 | c.119C>A p.P40H | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as CM041983, COSV100796770; called by muse, mutect2, varscan2
- ACTA2 | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); catalogued as rs757656209, COSV56516271, COSV56516933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTC1 | c.994A>T p.I332F | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99291950; called by muse, mutect2, varscan2
- ADAM22 | c.2406G>T p.K802N | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99716472, COSV99717422; called by muse, mutect2, varscan2
- ADAM7 | c.488C>G p.P163R | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.145); catalogued as COSV51544259, COSV99444285; called by muse, mutect2, varscan2
- ADAMTS13 | c.3632C>G p.A1211G | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV99390359; called by muse, mutect2, varscan2
- ADAMTS8 | c.1416C>A p.C472* | Nonsense Mutation (SNP) | VAF 16/103 reads (16%) | catalogued as rs369009464, COSV99961175; called by muse, mutect2, varscan2
- ADCY5 | c.3589G>C p.D1197H | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59196432; called by muse, mutect2
- ADGRV1 | c.17845T>A p.L5949I | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101316154; called by muse, mutect2, varscan2
- AFF3 | c.1150G>T p.A384S | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.271); catalogued as COSV100419393; called by muse, mutect2, varscan2
- AHCYL2 | c.1240A>G p.M414V | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100273537; called by muse, varscan2
- AHCYL2 | c.1295+1G>T p.X432_splice | Splice Site (SNP) | VAF 48/106 reads (45%) | catalogued as COSV100273542; called by muse, varscan2
- AHRR | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100327602; called by muse, mutect2, varscan2
- AKR1D1 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99653163; called by mutect2, varscan2
- ALPG | c.122C>A p.A41D | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV54968172, COSV99779386; called by muse, mutect2, varscan2
- ALPK2 | c.5069C>G p.S1690C | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.125); catalogued as COSV100864519; called by muse, mutect2, varscan2
- ANK2 | c.2694-1G>C p.X898_splice | Splice Site (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100002496; called by muse, mutect2, varscan2
- AP002512.3 | c.974T>C p.V325A | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs1386795821, COSV99688022; called by muse, mutect2, varscan2
- APBA2 | c.764A>T p.E255V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); catalogued as rs1186094661, COSV101382352; called by muse, mutect2, varscan2
- APOB | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99263768, COSV99266413; called by muse, mutect2, varscan2
- APOBEC1 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99981132; called by muse, mutect2, varscan2
- APOBR | c.2677G>T p.G893W (on ENST00000431282; = p.G902W on NM_018690.4) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100112684; called by muse, mutect2, varscan2
- ARHGAP11A | c.445A>G p.T149A | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV100853273; called by muse, mutect2, varscan2
- ARHGAP17 | c.223G>C p.A75P | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99253666; called by muse, mutect2, varscan2
- ARHGAP35 | c.3256G>A p.D1086N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as COSV101351277; called by muse, mutect2, varscan2
- ARHGAP35 | c.3564G>C p.K1188N | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.239); catalogued as COSV101351279; called by muse, mutect2, varscan2
- ARMC6 | c.1237G>T p.G413W (on ENST00000392336; = p.G388W on NM_033415.4) | Missense Mutation (SNP) | VAF 76/134 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99523084; called by muse, mutect2, varscan2
- ARPP21 | c.1744C>A p.L582I | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV51791645, COSV99492444; called by muse, mutect2, varscan2
- ASB15 | c.1600C>A p.P534T | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.759); catalogued as COSV51929941, COSV99306742; called by muse, mutect2, varscan2
- ASCC3 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV100225966; called by muse, mutect2, varscan2
- ASIC3 | c.274T>A p.C92S | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99874624; called by muse, mutect2, varscan2
- ASPM | c.3122G>A p.R1041K | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV99660666; called by muse, mutect2, varscan2
- ASXL1 | c.1162_1163del p.V388Pfs*21 | Frame Shift Del (DEL) | VAF 14/118 reads (12%) | catalogued as rs886043994; called by pindel, varscan2
- ATAD2 | c.3503A>G p.K1168R | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99784909; called by muse, mutect2, varscan2
- ATAD2B | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53195895; called by muse, mutect2, varscan2
- ATP11C | c.2043G>A p.M681I | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.588); catalogued as COSV100558199; called by muse, mutect2, varscan2
- ATP11C | c.1416T>A p.C472* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as COSV100558200; called by muse, mutect2, varscan2
- ATP2B4 | c.2738C>A p.S913* | Nonsense Mutation (SNP) | VAF 23/105 reads (22%) | catalogued as COSV100397710, COSV58181386; called by muse, mutect2, varscan2
- ATRN | c.2302G>T p.D768Y | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV99497394; called by muse, mutect2, varscan2
- BBS12 | c.1155G>A p.M385I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV100045002; called by muse, mutect2, varscan2
- BCAS3 | c.1513A>T p.N505Y | Missense Mutation (SNP) | VAF 93/341 reads (27%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.986); catalogued as COSV101176284; called by muse, mutect2, varscan2
- BCAT1 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99678705; called by muse, mutect2, varscan2
- BMI1 | c.821G>C p.S274T | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV100936432, COSV64959587; called by muse, mutect2, varscan2
- BRCA1 | c.2611C>T p.P871S | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV58801330; called by muse, mutect2, varscan2
- BRD8 | c.2738A>T p.E913V | Missense Mutation (SNP) | VAF 123/271 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.282); catalogued as COSV99137189; called by muse, mutect2, varscan2
- BRINP2 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as rs748381466, COSV64181144; called by muse, mutect2, varscan2
- C11orf42 | c.515A>C p.Q172P | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99792215; called by muse, mutect2, varscan2
- C3AR1 | c.137G>A p.W46* | Nonsense Mutation (SNP) | VAF 28/106 reads (26%) | catalogued as COSV99368720; called by muse, mutect2, varscan2
- C3orf56 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs372913944; called by muse, mutect2, varscan2
- C5orf15 | c.394C>G p.L132V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as COSV99198333; called by muse, mutect2, varscan2
- C6 | c.2084G>A p.G695E | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV99667359; called by muse, mutect2, varscan2
- C8A | c.337C>A p.L113I | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100776565, COSV100776650; called by muse, mutect2, varscan2
- CACNA1C | c.252G>T p.Q84H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100219807; called by muse, mutect2, varscan2
- CACNA2D4 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99765949; called by muse, mutect2, varscan2
- CAMK2A | c.1100A>T p.E367V (on ENST00000348628 / NM_171825.2; = p.E378V on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100652056; called by muse, mutect2, varscan2
- CASP5 | c.71G>T p.S24I | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99507800; called by muse, mutect2, varscan2
- CASR | c.925C>G p.Q309E | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99949162; called by muse, mutect2, varscan2
- CBARP | c.3G>T p.M1? (on ENST00000382477; = p.M7I on NM_152769.3) | Translation Start Site (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.041); catalogued as COSV99289733; called by muse, varscan2
- CBX7 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs1415800550, COSV53359053; called by muse, mutect2, varscan2
- CCDC130 | c.458A>T p.E153V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV99681283; called by muse, mutect2, varscan2
- CCDC150 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99777111; called by muse, mutect2, varscan2
- CCDC42 | c.295-2A>T p.X99_splice | Splice Site (SNP) | VAF 13/23 reads (57%) | catalogued as COSV99549828; called by muse, mutect2, varscan2
- CCDC88B | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.084); catalogued as rs771813182, COSV100105609; called by muse, mutect2, varscan2
- CCK | c.300G>T p.W100C | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100589049, COSV100589056; called by muse, mutect2, varscan2
- CCT6A | c.1234G>T p.G412C | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99303561; called by muse, mutect2, varscan2
- CDH18 | c.1378G>C p.A460P | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99936152; called by muse, mutect2, varscan2
- CDH9 | c.683A>T p.N228I | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.381); catalogued as COSV99146088; called by muse, mutect2, varscan2
- CDHR2 | c.2125C>A p.P709T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as rs1354157460, COSV56135752, COSV99991814; called by muse, mutect2, varscan2
- CENPE | c.4796A>T p.Q1599L | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.864); catalogued as COSV99478388; called by muse, mutect2, varscan2
- CEP128 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99383427; called by muse, mutect2, varscan2
- CER1 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 51/116 reads (44%) | catalogued as COSV101097885, COSV66603380; called by muse, mutect2, varscan2
- CFAP65 | c.2066C>T p.T689M | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as rs769586505, COSV58559280; called by muse, mutect2, varscan2
- CFAP65 | c.448G>C p.E150Q (on ENST00000341552 / NM_194302.4; = p.E85Q on NM_152389.4) | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.105); catalogued as COSV99838376; called by muse, mutect2, varscan2
- CFAP69 | c.1032A>T p.E344D | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100290249; called by muse, mutect2, varscan2
- CHD1 | c.4788A>G p.R1596= | Splice Region (SNP) | VAF 18/47 reads (38%) | catalogued as COSV99399591; called by muse, mutect2, varscan2
- CILK1 | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as CM090758, COSV100607836; called by muse, mutect2, varscan2
- CLEC14A | c.521A>G p.Q174R | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1401023737, COSV100643621; called by muse, mutect2, varscan2
- COL19A1 | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV100506685; called by muse, mutect2, varscan2
- COPS4 | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV100018690; called by muse, mutect2, varscan2
- CPN1 | c.183C>G p.Y61* | Nonsense Mutation (SNP) | VAF 56/76 reads (74%) | catalogued as COSV100962652; called by muse, mutect2, varscan2
- CPS1 | c.1463C>A p.T488N | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.532); catalogued as COSV99243392; called by muse, mutect2, varscan2
- CPSF2 | c.1179A>T p.E393D | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV100102955; called by muse, mutect2, varscan2
- CREB3L2 | c.1354G>T p.G452C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as rs750933727, COSV100382075; called by muse, mutect2, varscan2
- CRLF1 | c.763G>T p.V255L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.943); catalogued as COSV100679006, COSV62260985; called by muse, mutect2, varscan2
- CSMD2 | c.5707A>T p.T1903S | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV99591928; called by muse, mutect2, varscan2
- CSMD3 | c.7399G>T p.G2467* (on ENST00000297405 / NM_001363185.1; = p.G2363* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 12/105 reads (11%) | catalogued as COSV99823747; called by muse, mutect2, varscan2
- CSMD3 | c.3689G>T p.W1230L (on ENST00000297405 / NM_001363185.1; = p.W1126L on NM_052900.3) | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99838546; called by muse, mutect2, varscan2
- CSPG4 | c.3040G>T p.V1014L | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as COSV100413882, COSV57893036; called by muse, mutect2, varscan2
- CST2 | c.120T>A p.N40K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.288); catalogued as rs1426985246, COSV100491253; called by muse, mutect2, varscan2
- CUBN | c.2432C>A p.A811D | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100913019; called by muse, mutect2, varscan2
- CUL1 | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV100296751; called by muse, mutect2, varscan2
- CWF19L2 | c.2161G>A p.A721T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs775560292, COSV99979324; called by muse, mutect2, varscan2
- CWH43 | c.455C>G p.S152C | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV99893616; called by muse, mutect2, varscan2
- CYFIP1 | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100488436; called by muse, mutect2, varscan2
- CYP3A43 | c.1438C>A p.L480I (on ENST00000354829 / NM_057095.3; = p.L481I on NM_022820.5) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV99733333; called by muse, mutect2, varscan2
- DAXX | c.1601C>G p.S534* | Nonsense Mutation (SNP) | VAF 15/104 reads (14%) | catalogued as COSV56472855, COSV99802307; called by muse, mutect2, varscan2
- DAXX | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV56468832; called by muse, mutect2, varscan2
- DAXX | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99802311; called by muse, mutect2, varscan2
- DBN1 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52788476; called by muse, mutect2, varscan2
- DBR1 | c.1058C>A p.P353Q | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.472); catalogued as COSV99604563; called by muse, mutect2
- DCAF10 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99647774; called by muse, mutect2, varscan2
- DCAF4L2 | c.123C>A p.N41K | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV100151032; called by muse, mutect2, varscan2
- DCAF8L1 | c.1314C>A p.D438E | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV101491485, COSV71595525; called by muse, mutect2, varscan2
- DCDC1 | c.2664G>C p.W888C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV100338461; called by mutect2, varscan2
- DCUN1D2 | c.342G>T p.Q114H | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100215251; called by muse, mutect2, varscan2
- DGKD | c.819+1G>C p.X273_splice (on ENST00000264057 / NM_152879.3; = p.X229_splice on NM_003648.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 22/61 reads (36%) | catalogued as COSV99896758; called by muse, mutect2, varscan2
- DHX15 | c.2048G>T p.R683M | Missense Mutation (SNP) | VAF 66/290 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV100391501; called by muse, mutect2, varscan2
- DHX38 | c.2645C>T p.T882I | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV99194397; called by muse, mutect2, varscan2
- DICER1 | c.5137G>T p.D1713Y | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100602232; called by muse, mutect2, varscan2
- DIDO1 | c.3935C>T p.S1312L | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV99826312; called by muse, mutect2, varscan2
- DLK1 | c.158T>A p.L53H | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.926); catalogued as COSV100375307; called by muse, mutect2, varscan2
- DLK1 | c.457C>A p.H153N | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.761); catalogued as COSV100375262, COSV100375308; called by muse, mutect2, varscan2
- DLK1 | c.458A>T p.H153L | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV100375311; called by muse, mutect2, varscan2
- DMD | c.6421T>C p.Y2141H | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV100820682; called by muse, mutect2, varscan2
- DNAH11 | c.8303A>G p.Y2768C | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100179683; called by muse, mutect2, varscan2
- DNAH9 | c.8855C>T p.T2952I | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs553790907, COSV52360288, COSV99306592; called by muse, mutect2, varscan2
- DNAI4 | c.1515T>G p.Y505* | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | catalogued as COSV100925286; called by muse, mutect2, varscan2
- DNASE1 | c.192C>A p.D64E | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99892575; called by muse, mutect2, varscan2
- DNER | c.1953C>G p.I651M | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV100519137, COSV59165708; called by muse, mutect2, varscan2
- DPP10 | c.2004T>A p.F668L | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.812); catalogued as COSV100068300, COSV59662592; called by muse, mutect2, varscan2
- DSPP | c.1073G>T p.R358I | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.065); catalogued as COSV56808409; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.853A>T p.S285C | Missense Mutation (SNP) | VAF 141/228 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV100668681; called by muse, mutect2, varscan2
- EFEMP1 | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100816893; called by muse, mutect2, varscan2
- EPG5 | c.4385C>T p.T1462I | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99957598; called by muse, mutect2, varscan2
- EPHA5 | c.2330T>A p.L777H | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99899762; called by muse, mutect2, varscan2
- EPHA5 | c.1294C>A p.L432I | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.483); catalogued as COSV99899764; called by muse, mutect2, varscan2
- EPHB1 | c.1183A>T p.S395C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV101213416; called by muse, mutect2, varscan2
- ERBIN | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99397207; called by muse, mutect2, varscan2
- ERICH3 | c.3640G>A p.G1214R | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV100444842; called by muse, mutect2, varscan2
- ESRRB | c.432G>T p.E144D | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.101); catalogued as rs777541893, COSV55067054; called by muse, mutect2, varscan2
- ETAA1 | c.2503T>C p.F835L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.077); catalogued as COSV99712836; called by muse, mutect2, varscan2
- EXT2 | c.828T>A p.H276Q (on ENST00000343631; = p.H309Q on NM_000401.3) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100640638; called by muse, mutect2, varscan2
- F5 | c.5588C>T p.P1863L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as rs1464582597, COSV100889158; called by muse, mutect2, varscan2
- FAM135B | c.833C>A p.A278D | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV52712167, COSV99425280; called by muse, mutect2, varscan2
- FARP1 | c.709G>T p.G237C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100131211; called by muse, mutect2, varscan2
- FASTKD1 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV101328515; called by muse, mutect2, varscan2
- FCRL1 | c.899C>A p.A300D | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV63826670; called by muse, mutect2, varscan2
- FGD5 | c.1193G>C p.G398A | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.19); catalogued as COSV99548530; called by muse, mutect2, varscan2
- FGF14 | c.735G>C p.K245N | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.101); catalogued as COSV101086786, COSV65945779; called by muse, mutect2, varscan2
- FKBP15 | c.3137C>G p.P1046R | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99439188, COSV99440118; called by muse, mutect2, varscan2
- FLNC | c.6760G>T p.V2254L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100368338; called by muse, mutect2
- FLVCR1 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as rs1325812623, COSV100757926; called by muse, mutect2, varscan2
- FMN2 | c.2251G>C p.E751Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV100145962, COSV60430513; called by muse, mutect2, varscan2
- FMO3 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100882491; called by muse, mutect2, varscan2
- FOXJ2 | c.565G>T p.G189W | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99368715; called by muse, mutect2, varscan2
- FOXP4 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.056); catalogued as COSV57222953; called by muse, mutect2, varscan2
- FPGT | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100907321; called by muse, mutect2, varscan2
- FRMD4B | c.3062G>T p.R1021I | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV101273526; called by muse, mutect2, varscan2
- FRYL | c.5288G>T p.G1763V | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99977347; called by muse, mutect2, varscan2
- FSTL5 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.159); catalogued as COSV60211764; called by muse, mutect2, varscan2
- GAL3ST1 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs150519649, COSV58891997; called by muse, mutect2, varscan2
- GALC | c.1337G>T p.W446L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99730034; called by muse, mutect2
- GATM | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV101188328; called by muse, mutect2, varscan2
- GJA8 | c.748A>G p.K250E | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99569522; called by muse, mutect2, varscan2
- GLI3 | c.3617G>A p.R1206K | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs776871680, COSV101229934; called by muse, mutect2, varscan2
- GLIPR1L2 | c.308T>C p.L103S | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100248664; called by muse, mutect2, varscan2
- GLYAT | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.133); catalogued as COSV53539948; called by muse, mutect2, varscan2
- GNPAT | c.1960G>A p.V654M | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV100791648; called by muse, mutect2, varscan2
- GPR137B | c.116C>G p.P39R | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as rs199613305, COSV100858353, COSV63991293; called by muse, mutect2, varscan2
- GPX2 | c.505T>A p.Y169N | Missense Mutation (SNP) | VAF 81/198 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100767462; called by muse, mutect2, varscan2
- GRHL3 | c.953C>G p.A318G (on ENST00000350501 / NM_198174.3; = p.A323G on NM_021180.3) | Missense Mutation (SNP) | VAF 101/323 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1334073661, COSV99359499; called by muse, mutect2, varscan2
- GRIK4 | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 64/264 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV101483645; called by mutect2, varscan2
- GRIN2A | c.3052G>A p.V1018M | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs775756583, COSV58020685; called by muse, mutect2, varscan2
- GRIP1 | c.137A>T p.E46V | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99669982; called by muse, mutect2, varscan2
- GRK4 | c.186A>G p.I62M (on ENST00000398052 / NM_182982.3; = p.I30M on NM_005307.3) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369672282; called by muse, mutect2, varscan2
- GRM4 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.444); catalogued as COSV100946460; called by muse, mutect2, varscan2
- GRM8 | c.412C>G p.P138A | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV100284038, COSV58842856; called by muse, mutect2, varscan2
- GSTA2 | c.87G>A p.E29= | Splice Region (SNP) | VAF 23/107 reads (21%) | catalogued as rs568358018, COSV101534051; called by muse, mutect2, varscan2
- GTSE1 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 110/244 reads (45%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.637); catalogued as COSV101483224; called by muse, mutect2, varscan2
- GTSF1L | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV65932777; called by muse, mutect2, varscan2
- GUCY1A2 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | catalogued as COSV99975327; called by muse, mutect2, varscan2
- H2AC8 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.017); catalogued as COSV99773282; called by muse, mutect2, varscan2
- HCFC1 | c.4777G>C p.A1593P | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.638); catalogued as COSV100129418; called by muse, mutect2, varscan2
- HDDC3 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100376599; called by muse, mutect2, varscan2
- HFM1 | c.2422G>C p.D808H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.259); catalogued as COSV99646251; called by muse, mutect2, varscan2
- HLA-B | c.1005G>C p.K335N | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as COSV69523129; called by muse, mutect2, varscan2
- HLA-B | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as rs41559613, CM015109, COSV101318127, COSV101318294, COSV69522021; called by muse, mutect2, varscan2
- HLX | c.17T>A p.L6Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as COSV100854564; called by muse, varscan2
- HOXD11 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV99983298; called by muse, mutect2, varscan2
- HOXD11 | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99983300; called by muse, mutect2, varscan2
- HYDIN | c.14732A>T p.D4911V | Missense Mutation (SNP) | VAF 210/478 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as COSV101125122; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 93/386 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs764646982; called by muse, mutect2, varscan2
- IGSF9B | c.157G>C p.G53R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100317959, COSV58068843; called by muse, mutect2
- IL4I1 | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV99680776; called by muse, mutect2, varscan2
- INF2 | c.2935G>A p.D979N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99384062; called by muse, mutect2
- INTS12 | c.851C>G p.S284W | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100415809; called by muse, mutect2
- ITLN1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.786); catalogued as COSV100406268; called by muse, mutect2, varscan2
- JAKMIP1 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs762424724, COSV51529563, COSV99290023; called by muse, mutect2, varscan2
- KALRN | c.1905G>T p.Q635H | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV99565439; called by muse, mutect2, varscan2
- KCNMA1 | c.2569C>A p.L857I (on ENST00000286628 / NM_001161352.2; = p.L799I on NM_002247.4) | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV99698348; called by muse, mutect2, varscan2
- KCNN2 | c.1654A>C p.T552P (on ENST00000264773; = p.T764P on NM_021614.4) | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV53302400, COSV99300100; called by muse, mutect2, varscan2
- KDR | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV99818072; called by muse, mutect2, varscan2
- KEL | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV62337980; called by muse, mutect2, varscan2
- KHK | c.543G>T p.Q181H | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV99565235; called by muse, mutect2, varscan2
- KIAA0586 | c.3026G>C p.R1009T (on ENST00000619416 / NM_001244190.2; = p.R948T on NM_014749.5) | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as COSV99708394; called by muse, mutect2
- KIAA1586 | c.1714G>T p.G572* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as COSV100875363; called by muse, mutect2, varscan2
- KIFC3 | c.273G>T p.W91C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV101109246; called by muse, mutect2, varscan2
- KIR3DL3 | c.1060G>T p.V354F | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV99400016; called by muse, mutect2, varscan2
- KIRREL1 | c.1290G>T p.E430D | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV100779996; called by muse, mutect2, varscan2
- KIRREL3 | c.1957T>A p.S653T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.179); catalogued as COSV101375205; called by muse, mutect2, varscan2
- KLHDC9 | c.356C>G p.A119G | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.17); catalogued as COSV100919677; called by muse, mutect2
- KLRC3 | c.533G>C p.R178P | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768046359, COSV101122914, COSV67251385; called by muse, mutect2, varscan2
- KPRP | c.1114C>A p.P372T | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV64222531; called by muse, mutect2, varscan2
- KRT1 | c.843G>C p.E281D | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1168760153, COSV52869137, COSV99358815, COSV99358859; called by muse, mutect2, varscan2
- KRT6A | c.1477G>A p.V493I | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs201432146, COSV58105498; called by muse, mutect2, varscan2
- KRTAP10-5 | c.619C>G p.P207A | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as rs1343046020, COSV100554348; called by muse, mutect2, varscan2
- KRTAP13-4 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100481767; called by muse, varscan2
- KRTAP4-3 | c.350C>G p.S117C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV101194164; called by muse, mutect2, varscan2
- KRTAP4-3 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV66941077; called by muse, mutect2, varscan2
- LAMA3 | c.1264G>A p.G422S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV100557094; called by muse, mutect2, varscan2
- LARP7 | c.553-1G>T p.X185_splice | Splice Site (SNP) | VAF 23/103 reads (22%) | catalogued as COSV100135230; called by muse, mutect2, varscan2
- LATS1 | c.1604del p.G535Efs*6 | Frame Shift Del (DEL) | VAF 51/137 reads (37%) | catalogued as COSV53593815; called by mutect2, pindel, varscan2
- LCE2A | c.210C>G p.S70R | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.469); catalogued as COSV100909180; called by muse, mutect2, varscan2
- LENG8 | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100457703; called by muse, mutect2, varscan2
- LGALS9C | c.673-2A>T p.X225_splice | Splice Site (SNP) | VAF 35/65 reads (54%) | catalogued as COSV100055673; called by muse, mutect2, varscan2
- LGR4 | c.2399T>C p.L800P | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100156621; called by muse, mutect2, varscan2
- LILRB4 | c.1300G>T p.G434W (on ENST00000391733 / NM_001278428.3; = p.G433W on NM_001278426.3) | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99553592, COSV99553933; called by muse, varscan2
- LILRB4 | c.1315G>T p.E439* (on ENST00000391733 / NM_001278428.3; = p.E438* on NM_001278426.3) | Nonsense Mutation (SNP) | VAF 49/148 reads (33%) | catalogued as COSV99553934; called by muse, varscan2
- LRIT2 | c.1519C>A p.P507T | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.038); catalogued as COSV100259097; called by muse, mutect2, varscan2
- LRP5 | c.1171G>C p.D391H | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99592284; called by muse, mutect2
- LRPPRC | c.2904C>A p.N968K | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as COSV53242699, COSV99580949; called by muse, mutect2, varscan2
- LRRC7 | c.4400G>T p.R1467L (on ENST00000651989 / NM_001370785.2; = p.R1387L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV99227906; called by muse, mutect2, varscan2
- LRRIQ1 | c.455-2A>G p.X152_splice | Splice Site (SNP) | VAF 33/64 reads (52%) | catalogued as COSV101277725; called by muse, mutect2, varscan2
- LRRTM2 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0.045); catalogued as rs781776155, COSV99217821; called by muse, mutect2, varscan2
- LY6G6D | c.180C>T p.P60= | Splice Region (SNP) | VAF 43/335 reads (13%) | catalogued as rs765488159, COSV101010834; called by muse, mutect2, varscan2
- LZTR1 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99301999; called by muse, mutect2, varscan2
- MAGEA1 | c.838C>A p.L280I | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as COSV100756660; called by muse, mutect2, varscan2
- MAGI3 | c.1823A>T p.Q608L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV100289620; called by muse, mutect2, varscan2
- MAN2C1 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV99145536; called by muse, mutect2, varscan2
- MAP3K19 | c.1693C>A p.H565N | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV100208803; called by muse, mutect2, varscan2
- MEIS1 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 112/266 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99715405; called by muse, mutect2, varscan2
- METTL14 | c.1241G>A p.R414K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV101183408; called by muse, mutect2, varscan2
- MICAL2 | c.1144C>A p.L382M | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.688); catalogued as COSV99817847; called by muse, mutect2, varscan2
- MINDY1 | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 18/127 reads (14%) | catalogued as COSV100385493; called by muse, mutect2, varscan2
- MMD | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100017885; called by muse, mutect2, varscan2
- MMP20 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99497787; called by muse, mutect2, varscan2
- MMRN1 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.53); catalogued as COSV99307376; called by muse, mutect2, varscan2
- MON1A | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as rs1559491612, COSV99616832; called by muse, mutect2, varscan2
- MPO | c.1351G>T p.G451W | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56567645; called by muse, mutect2, varscan2
- MROH2B | c.3464T>A p.V1155D | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV101270773; called by muse, mutect2, varscan2
- MROH7 | c.1879G>T p.G627C | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.467); catalogued as COSV100273703; called by muse, mutect2, varscan2
- MSH4 | c.2555C>T p.S852L | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV99591990; called by muse, mutect2, varscan2
- MTSS1 | c.73-2A>T p.X25_splice | Splice Site (SNP) | VAF 39/116 reads (34%) | catalogued as COSV100275131; called by muse, mutect2, varscan2
- MUC16 | c.30908G>T p.S10303I | Missense Mutation (SNP) | VAF 67/112 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV101200340; called by muse, mutect2, varscan2
- MUC17 | c.12149A>G p.E4050G | Missense Mutation (SNP) | VAF 79/206 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100074022; called by muse, mutect2, varscan2
- MUC5B | c.13093G>T p.V4365L | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV101500502; called by muse, mutect2, varscan2
- MXI1 | c.244C>A p.H82N | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV99491409; called by muse, mutect2, varscan2
- MYBPC2 | c.1385T>C p.V462A | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100731895; called by muse, mutect2
- MYCT1 | c.526C>A p.L176I | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.723); catalogued as COSV100924077; called by muse, mutect2, varscan2
- MYH1 | c.3833C>A p.T1278K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV99876305; called by muse, mutect2, varscan2
- MYH11 | c.408G>C p.E136D | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV100259468; called by muse, mutect2, varscan2
- MYH9 | c.1769A>G p.D590G | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99339231; called by muse, mutect2, varscan2
- MYO15A | c.2864G>T p.R955M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV99233419; called by muse, mutect2, varscan2
- MYO6 | c.1487A>G p.Y496C | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100889379; called by muse, mutect2, varscan2
- N4BP1 | c.1121C>A p.S374Y | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99285338; called by muse, mutect2, varscan2
- NALCN | c.3584-1G>C p.X1195_splice | Splice Site (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99216136; called by muse, mutect2
- NBAS | c.332T>A p.I111N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV99870487; called by muse, mutect2, varscan2
- NCAPD2 | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 42/131 reads (32%) | catalogued as COSV100217296; called by muse, mutect2, varscan2
- NCR3 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99279118; called by muse, mutect2, varscan2
- NETO1 | c.355G>T p.G119* | Nonsense Mutation (SNP) | VAF 65/170 reads (38%) | catalogued as COSV100199049; called by muse, mutect2, varscan2
- NEURL4 | c.1590G>T p.K530N | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.828); catalogued as COSV100224401; called by muse, mutect2, varscan2
- NFKBIZ | c.1364G>T p.G455V | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100397116; called by muse, mutect2, varscan2
- NKPD1 | c.2345G>T p.R782L | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.323); catalogued as COSV99674950; called by muse, mutect2
- NLRP4 | c.1861G>C p.D621H | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.458); catalogued as COSV100016619; called by muse, mutect2, varscan2
- NME7 | c.742G>C p.A248P | Missense Mutation (SNP) | VAF 108/341 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV100891083; called by muse, mutect2, varscan2
- NOTCH4 | c.1739-2A>G p.X580_splice | Splice Site (SNP) | VAF 29/85 reads (34%) | catalogued as COSV100900770; called by muse, mutect2, varscan2
- NR1I3 | c.884C>G p.T295S (on ENST00000367982 / NM_001077480.3; = p.T291S on NM_005122.5) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV100915764; called by muse, mutect2, varscan2
- NR4A2 | c.1694T>A p.L565H | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100277246; called by muse, mutect2, varscan2
- NR4A2 | c.1541A>T p.E514V | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100277248; called by muse, mutect2, varscan2
- NRCAM | c.1409G>A p.R470K (on ENST00000379028 / NM_001371124.1; = p.R464K on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1417009225, COSV100694639, COSV100694922; called by muse, mutect2, varscan2
- NSD3 | c.711A>C p.K237N | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as COSV100388746; called by muse, mutect2, varscan2
- NUP210L | c.3361C>A p.Q1121K | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.388); catalogued as COSV55141643; called by muse, mutect2, varscan2
- OAS3 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV99966391; called by muse, mutect2, varscan2
- OPCML | c.514C>A p.L172M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); catalogued as COSV100102729; called by muse, mutect2, varscan2
- OR10H2 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100008814; called by muse, mutect2, varscan2
- OR11G2 | c.870C>G p.Y290* | Nonsense Mutation (SNP) | VAF 70/189 reads (37%) | catalogued as rs376290528, COSV100639985, COSV62131923; called by muse, mutect2, varscan2
- OR14K1 | c.841C>G p.P281A | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99315298; called by muse, mutect2, varscan2
- OR1C1 | c.782G>T p.S261I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.611); catalogued as COSV68715632; called by muse, mutect2, varscan2
- OR2AK2 | c.506G>T p.C169F | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs147425585; called by muse, mutect2, varscan2
- OR2B3 | c.702del p.Q235Kfs*11 | Frame Shift Del (DEL) | VAF 27/89 reads (30%) | catalogued as COSV65851106; called by mutect2, pindel, varscan2
- OR2G6 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); catalogued as rs750002705, COSV58574407, COSV58575859; called by muse, mutect2, varscan2
- OR2T34 | c.121T>A p.L41M | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as COSV100170413; called by muse, mutect2, varscan2
- OR2W3 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs761032797, COSV100831736; called by muse, mutect2, varscan2
- OR4E2 | c.853T>G p.F285V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100330116; called by muse, mutect2, varscan2
- OR4M1 | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV100271314; called by muse, mutect2, varscan2
- OR4N2 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs368630542, COSV60050638; called by muse, varscan2
- OR51E2 | c.836A>G p.Y279C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101211366, COSV67806760; called by muse, mutect2, varscan2
- OR52E4 | c.124G>T p.V42L | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100389293; called by muse, mutect2, varscan2
- OR52E8 | c.448A>T p.I150F | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV101190520; called by muse, mutect2, varscan2
- OR52H1 | c.886G>T p.V296L (on ENST00000322653; = p.V302L on NM_001005289.1) | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV100497343; called by muse, mutect2, varscan2
- OR5AS1 | c.428G>T p.C143F | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.419); catalogued as COSV100546318; called by muse, mutect2, varscan2
- OR5L1 | c.898G>C p.A300P | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100450104; called by muse, mutect2, varscan2
- OR5L2 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as COSV101004351, COSV65724976; called by muse, mutect2, varscan2
- OR5T3 | c.108A>T p.Q36H | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV100282856, COSV57379534; called by muse, mutect2, varscan2
- OR8U1 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.213); catalogued as COSV56418496; called by muse, mutect2, varscan2
- OTOF | c.5306A>T p.Q1769L (on ENST00000272371 / NM_194248.3; = p.Q1002L on NM_004802.4) | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99718140; called by muse, mutect2, varscan2
- OTOF | c.5197G>T p.E1733* (on ENST00000272371 / NM_194248.3; = p.E966* on NM_004802.4) | Nonsense Mutation (SNP) | VAF 40/136 reads (29%) | catalogued as CM091231, COSV55501472, COSV99718143; called by muse, mutect2, varscan2
- P2RY8 | c.961C>G p.R321G | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101184089, COSV67177063; called by muse, mutect2, varscan2
- PACRGL | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as COSV54842330, COSV54843129, COSV99764250; called by muse, mutect2, varscan2
- PAG1 | c.824A>T p.E275V | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.318); catalogued as rs780388349, COSV99597633; called by muse, mutect2, varscan2
- PAPPA2 | c.1718A>T p.H573L | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100866861; called by muse, mutect2
- PCDH10 | c.634G>C p.V212L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV99993935; called by muse, mutect2, varscan2
- PCDH15 | c.4998del p.A1667Qfs*153 | Frame Shift Del (DEL) | VAF 17/40 reads (43%) | catalogued as COSV100905987; called by mutect2, pindel, varscan2
- PCDHA10 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.072); catalogued as COSV100251756; called by muse, mutect2, varscan2
- PCDHA9 | c.2086G>A p.V696I | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV100969777; called by muse, mutect2, varscan2
- PCDHGC4 | c.90G>T p.Q30H | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99340912; called by muse, mutect2, varscan2
- PCNX1 | c.6133G>T p.G2045C | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99456161; called by muse, mutect2, varscan2
- PDE3B | c.1957-1G>T p.X653_splice | Splice Site (SNP) | VAF 21/89 reads (24%) | catalogued as COSV99962026, COSV99962797; called by muse, mutect2, varscan2
- PDE8B | c.1481C>T p.T494I | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.206); catalogued as COSV99367062; called by muse, mutect2, varscan2
- PDIA5 | c.195G>T p.R65S | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as COSV100299543; called by muse, mutect2, varscan2
- PER1 | c.2408G>T p.R803M | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV100424659; called by muse, mutect2, varscan2
- PGBD5 | c.1156G>A p.D386N (on ENST00000525115; = p.D455N on NM_001258311.2) | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV100358694; called by muse, mutect2, varscan2
- PGD | c.1354G>C p.A452P | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99581499; called by muse, mutect2, varscan2
- PGLYRP2 | c.426G>T p.L142F | Missense Mutation (SNP) | VAF 63/115 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV52991978, COSV99484108; called by muse, mutect2, varscan2
- PITPNM1 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100711695; called by muse, mutect2
- PITX2 | c.59C>A p.A20E | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.047); catalogued as COSV100721706; called by muse, mutect2, varscan2
- PKDREJ | c.6334G>T p.G2112C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99479108; called by muse, mutect2, varscan2
- PKDREJ | c.3104C>A p.P1035H | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99479109; called by muse, mutect2, varscan2
- PKHD1 | c.1602G>T p.L534= | Splice Region (SNP) | VAF 12/43 reads (28%) | catalogued as rs1288930030, COSV100583618; called by muse, mutect2, varscan2
- PKHD1L1 | c.1142G>T p.W381L | Missense Mutation (SNP) | VAF 124/465 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.525); catalogued as COSV101006469; called by muse, mutect2, varscan2
- PLCG2 | c.2671G>C p.D891H | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100842424; called by muse, mutect2, varscan2
- PLCH1 | c.3563del p.N1188Mfs*12 (on ENST00000340059 / NM_001130960.2; = p.N1180Mfs*12 on NM_014996.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | catalogued as rs770857103; called by mutect2, pindel, varscan2
- PLK1 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100267310; called by muse, mutect2, varscan2
- PLPPR4 | c.1390G>C p.V464L | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV64566733; called by muse, mutect2, varscan2
- POLA1 | c.2806C>T p.P936S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.054); catalogued as COSV100985605; called by muse, mutect2, varscan2
- POLR3D | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100120141; called by muse, mutect2, varscan2
- PORCN | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as COSV100400470; called by muse, mutect2, varscan2
- POU3F1 | c.1052A>C p.K351T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100884711; called by muse, mutect2, varscan2
- PPIA | c.160C>G p.H54D | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.575); catalogued as COSV63533975; called by muse, mutect2, varscan2
- PPM1G | c.1548G>C p.E516D | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV52011317, COSV99277714; called by muse, mutect2, varscan2
- PRDM2 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99342068; called by muse, mutect2, varscan2
- PREX2 | c.4422G>T p.R1474S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV99908201; called by muse, mutect2, varscan2
- PRKG2 | c.832A>T p.R278* | Nonsense Mutation (SNP) | VAF 28/83 reads (34%) | catalogued as COSV100020066; called by muse, mutect2, varscan2
- PRUNE2 | c.3878T>A p.L1293Q | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV100944773; called by muse, mutect2, varscan2
- PSME4 | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.268); catalogued as COSV101122555; called by muse, mutect2, varscan2
- PTGS1 | c.1762G>T p.D588Y | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.375); catalogued as COSV99793105, COSV99793318; called by muse, mutect2, varscan2
- PTH2R | c.1573C>A p.L525I | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99782329; called by muse, mutect2, varscan2
- PTPRO | c.2906C>A p.T969K (on ENST00000281171 / NM_030667.3; = p.T941K on NM_002848.4) | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99840975; called by muse, mutect2, varscan2
- RAB2A | c.186G>T p.T62= | Splice Region (SNP) | VAF 15/59 reads (25%) | catalogued as COSV99389856; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2300A>G p.Y767C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51490409, COSV99921321; called by muse, mutect2
- RABGGTB | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs778000054, COSV100175157; called by muse, mutect2, varscan2
- RAD21 | c.1783G>T p.A595S | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.994); catalogued as COSV52063702, COSV99815352; called by muse, mutect2, varscan2
- RAPGEF2 | c.2577T>G p.S859R | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV100031367; called by muse, mutect2, varscan2
- RARS1 | c.1304G>T p.R435L | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as rs756878080, COSV99199138; called by muse, mutect2, varscan2
- RASGEF1A | c.88G>C p.G30R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100988655, COSV100988688; called by muse, mutect2
- RCAN3 | c.107T>A p.L36* | Nonsense Mutation (SNP) | VAF 30/89 reads (34%) | catalogued as rs1335268821, COSV100980348; called by muse, mutect2, varscan2
- RDX | c.234C>A p.F78L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.568); catalogued as COSV100562980, COSV58195404; called by muse, mutect2, varscan2
- REG3G | c.398G>T p.W133L | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99709552; called by muse, mutect2, varscan2
- RGS20 | c.886G>T p.E296* (on ENST00000297313 / NM_170587.4; = p.E149* on NM_003702.4) | Nonsense Mutation (SNP) | VAF 18/133 reads (14%) | catalogued as COSV99392258; called by muse, mutect2, varscan2
- RIMS1 | c.3707G>T p.G1236V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.785); catalogued as rs1055356005, COSV99328072; called by muse, mutect2, varscan2
- RNASE8 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100373522, COSV100373536; called by muse, mutect2, varscan2
- RORC | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100561998; called by muse, mutect2, varscan2
- RP1 | c.4806G>T p.Q1602H | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.014); catalogued as COSV99607993; called by muse, mutect2, varscan2
- RPS6KL1 | c.1280G>T p.R427L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.496); catalogued as COSV100665136; called by muse, mutect2, varscan2
- RRBP1 | c.420G>C p.K140N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99854240, COSV99854527; called by muse, mutect2, varscan2
- RTTN | c.5401C>T p.L1801F | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV99732920; called by muse, mutect2, varscan2
- RUNDC3B | c.343A>T p.R115* | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | catalogued as COSV55948075; called by muse, mutect2
- RUNX1T1 | c.1814A>G p.*605Wext*2 (on ENST00000265814 / NM_001198628.1; = p.*578Wext*2 on NM_004349.4 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99753015; called by muse, mutect2, varscan2
- RYR1 | c.3214C>T p.R1072C | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1307359469, COSV62103934; called by muse, mutect2, varscan2
- RYR2 | c.13306A>T p.K4436* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100771483; called by muse, mutect2, varscan2
- RYR3 | c.2009A>T p.D670V | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.668); catalogued as COSV101213135; called by muse, mutect2, varscan2
- RYR3 | c.10337C>A p.T3446K (on ENST00000389232; = p.T3447K on NM_001036.6) | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV101213136; called by muse, mutect2, varscan2
- SACS | c.12373G>T p.G4125* | Nonsense Mutation (SNP) | VAF 100/176 reads (57%) | catalogued as rs1326948780, COSV101207519; called by muse, mutect2, varscan2
- SAGE1 | c.2164G>T p.D722Y | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100187554; called by muse, mutect2, varscan2
- SALL2 | c.2723G>A p.S908N | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV100444466; called by muse, mutect2, varscan2
- SCN2A | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs761161877, COSV99332298; called by muse, mutect2, varscan2
- SCN2A | c.4272G>T p.W1424C | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99332300; called by muse, varscan2
- SEMA4D | c.2551G>T p.E851* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as rs778781300, COSV100358535; called by muse, mutect2, varscan2
- SEMA5A | c.2281A>G p.S761G | Missense Mutation (SNP) | VAF 34/327 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV101227774, COSV101228506; called by muse, mutect2, varscan2
- SEPHS2 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101529333; called by muse, mutect2, varscan2
- SEPTIN1 | c.1153G>C p.E385Q (on ENST00000321367; = p.E338Q on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.703); catalogued as COSV100363119; called by muse, mutect2, varscan2
- SERPINA10 | c.1030C>A p.Q344K | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.569); catalogued as rs149414832, COSV100003875; called by muse, mutect2, varscan2
- SESN2 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1160449364, COSV99455871; called by muse, mutect2, varscan2
- SFTPA2 | c.446A>T p.D149V | Missense Mutation (SNP) | VAF 479/668 reads (72%) | SIFT tolerated (0.2); PolyPhen benign (0.383); catalogued as COSV100958808; called by muse, mutect2, varscan2
- SHANK1 | c.2223G>T p.M741I | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as COSV99521518; called by muse, mutect2, varscan2
- SIGLEC1 | c.3844G>C p.A1282P | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV99167753; called by muse, mutect2, varscan2
- SLAMF1 | c.598C>A p.P200T | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs768444453, COSV99349410; called by muse, mutect2, varscan2
- SLC30A2 | c.664A>T p.R222* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100958576; called by muse, mutect2, varscan2
- SLC30A8 | c.662C>G p.A221G | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV101438586; called by muse, mutect2, varscan2
- SLC4A1 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 18/38 reads (47%) | catalogued as COSV52261325, COSV99293459; called by muse, mutect2, varscan2
- SLC6A13 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58261267; called by muse, mutect2, varscan2
- SLC7A9 | c.164T>A p.V55E | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99195362; called by muse, mutect2, varscan2
- SLC8A1 | c.874G>T p.D292Y | Missense Mutation (SNP) | VAF 113/365 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60498861; called by muse, mutect2, varscan2
- SLC9C2 | c.750G>T p.M250I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV100876847; called by muse, mutect2, varscan2
- SLCO4A1 | c.170A>C p.Q57P | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.177); catalogued as COSV99414864; called by muse, mutect2, varscan2
- SLIT1 | c.1819G>C p.G607R | Missense Mutation (SNP) | VAF 57/78 reads (73%) | SIFT tolerated (0.88); PolyPhen benign (0.118); catalogued as rs200826876, COSV56585129, COSV99821806; called by muse, mutect2, varscan2
- SLITRK2 | c.271C>T p.L91F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59425251, COSV59428776; called by muse, mutect2, varscan2
- SMG1 | c.5332G>T p.E1778* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as COSV101246350; called by muse, mutect2, varscan2
- SMG1 | c.3686A>G p.N1229S | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs759501589, COSV101246357; called by muse, mutect2, varscan2
- SNAPC4 | c.3657G>T p.R1219S | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100047411; called by muse, mutect2, varscan2
- SNTG1 | c.729T>G p.I243M | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV99384510; called by muse, mutect2, varscan2
- SOCS5 | c.85A>T p.N29Y | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV100125346; called by muse, mutect2, varscan2
- SORCS1 | c.1990G>T p.D664Y | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99036441; called by muse, mutect2, varscan2
- SPATA31E1 | c.2600C>G p.A867G | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.21); catalogued as rs878869892, COSV100350669; called by muse, mutect2, varscan2
- SPATA6 | c.1425A>T p.K475N | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV100893906; called by muse, mutect2, varscan2
- SPATA6 | c.769G>A p.V257M | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1387451436, COSV100893290; called by muse, mutect2, varscan2
- SPEG | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.065); catalogued as COSV100404936; called by muse, mutect2
- SPNS3 | c.1295G>T p.R432L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV100337057; called by muse, mutect2, varscan2
- SPOCK1 | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142164335; called by muse, mutect2, varscan2
- SPRYD3 | c.39C>A p.N13K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.077); catalogued as COSV100036793; called by muse, mutect2, varscan2
- SPTBN2 | c.3038C>T p.A1013V | Missense Mutation (SNP) | VAF 122/187 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV100019815; called by muse, mutect2, varscan2
- SRRM2 | c.2897G>A p.R966K | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); catalogued as COSV100071049; called by muse, mutect2, varscan2
- STAU2 | c.581C>T p.S194L (on ENST00000524300 / NM_001164380.2; = p.S162L on NM_014393.2) | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV63311352; called by muse, mutect2, varscan2
- STPG4 | c.485C>A p.T162K | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.197); catalogued as COSV99681355; called by muse, mutect2, varscan2
- STXBP5 | c.2981G>A p.R994K (on ENST00000321680 / NM_001127715.2; = p.R958K on NM_139244.4) | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.991); catalogued as COSV99470542; called by muse, mutect2, varscan2
- SUDS3 | c.851A>T p.K284I | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100820015; called by muse, mutect2, varscan2
- SULF2 | c.325A>C p.N109H | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100737254; called by muse, mutect2, varscan2
- SUPT6H | c.2662G>C p.E888Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.545); catalogued as COSV100112549; called by muse, varscan2
- SYNE1 | c.1933G>T p.D645Y (on ENST00000367255 / NM_182961.4; = p.D652Y on NM_033071.3) | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54988889, COSV99569923; called by muse, mutect2, varscan2
- SYNE2 | c.15410G>T p.R5137I | Missense Mutation (SNP) | VAF 62/399 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV100648023, COSV59973332; called by muse, mutect2, varscan2
- SYNPO2 | c.529C>G p.R177G | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs944638697, COSV100205889; called by muse, mutect2, varscan2
- SYNPO2 | c.1178G>T p.G393V | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100205890, COSV61112645; called by muse, mutect2, varscan2
- SYTL2 | c.2559G>C p.R853S (on ENST00000528231 / NM_001162951.2; = p.R829S on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100314479, COSV60362011; called by muse, mutect2, varscan2
- SYTL5 | c.1801G>C p.A601P | Missense Mutation (SNP) | VAF 56/89 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV99937412; called by muse, mutect2, varscan2
- TBC1D7 | c.312G>T p.Q104H | Missense Mutation (SNP) | VAF 89/285 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.308); catalogued as rs944392982, COSV100568646; called by muse, mutect2, varscan2
- TCHH | c.4348G>A p.E1450K | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.035); catalogued as rs1475446851, COSV100915231; called by muse, mutect2, varscan2
- TECRL | c.826C>A p.H276N | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs756764597, COSV101169097; called by muse, mutect2, varscan2
- TECRL | c.115C>A p.L39I | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV101169099; called by muse, mutect2, varscan2
- TECTA | c.4000G>T p.D1334Y | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs747039340, COSV99880227, COSV99880380; called by muse, mutect2, varscan2
- TENM3 | c.2292C>G p.C764W | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101305228; called by muse, mutect2, varscan2
- TENT5A | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.978); catalogued as COSV100199038; called by muse, mutect2, varscan2
- TFAP2E | c.1207A>G p.T403A | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); catalogued as COSV100951484; called by muse, mutect2, varscan2
- THSD7A | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV101448786, COSV101448946; called by muse, mutect2, varscan2
- THSD7A | c.855G>T p.K285N | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.142); catalogued as rs376959489; called by muse, mutect2, varscan2
- TINAG | c.1190G>T p.S397I | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.58); catalogued as COSV99450008; called by muse, mutect2, varscan2
- TJP1 | c.1022G>C p.R341T | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100632864; called by muse, mutect2, varscan2
- TMEM198 | c.945G>C p.P315= | Splice Region (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99524885, COSV99525063; called by mutect2, varscan2
- TMEM45A | c.551C>G p.S184* | Nonsense Mutation (SNP) | VAF 47/245 reads (19%) | catalogued as COSV100058481; called by muse, mutect2, varscan2
- TNFRSF11A | c.1429G>T p.G477C | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99500332; called by muse, mutect2, varscan2
- TNFRSF11A | c.1430G>T p.G477V | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99500335; called by muse, mutect2, varscan2
- TNFRSF1B | c.910C>G p.P304A | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.664); catalogued as COSV100884178; called by muse, mutect2
- TNNI3K | c.2354C>A p.A785D | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV100437137; called by muse, mutect2, varscan2
- TNR | c.1240C>T p.H414Y | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs78460048; called by muse, mutect2
- TNR | c.1239C>A p.T413= | Splice Region (SNP) | VAF 19/61 reads (31%) | catalogued as COSV54869486, COSV99690284; called by muse, mutect2
- TNRC6A | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as rs1196212897, COSV100170211; called by muse, mutect2, varscan2
- TNRC6A | c.3643-2A>C p.X1215_splice | Splice Site (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100170214; called by mutect2, varscan2
- TPP2 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.437); catalogued as COSV101060327; called by muse, mutect2, varscan2
- TPR | c.6323C>A p.S2108Y | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100824044; called by muse, mutect2, varscan2
- TRIM31 | c.9T>A p.S3R | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.321); catalogued as COSV100946820; called by muse, mutect2, varscan2
- TSHZ3 | c.1613A>G p.Q538R | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs867682858, COSV99551997; called by muse, mutect2, varscan2
- TSPAN12 | c.212G>T p.C71F | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV99763263; called by muse, mutect2, varscan2
- TTN | c.88447G>A p.D29483N (on ENST00000591111; = p.D22059N on NM_003319.4) | Missense Mutation (SNP) | VAF 26/212 reads (12%) | PolyPhen probably damaging (0.998); catalogued as COSV100619234; called by muse, mutect2, varscan2
- TTN | c.84431C>T p.S28144F (on ENST00000591111; = p.S20720F on NM_003319.4) | Missense Mutation (SNP) | VAF 44/112 reads (39%) | PolyPhen possibly damaging (0.711); catalogued as COSV100619235; called by muse, mutect2, varscan2
- TTN | c.68647C>A p.Q22883K (on ENST00000591111; = p.Q15459K on NM_003319.4) | Missense Mutation (SNP) | VAF 21/112 reads (19%) | PolyPhen possibly damaging (0.697); catalogued as rs753429609, COSV100619237, COSV60100542; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.21385G>A p.A7129T (on ENST00000591111; = p.A6202T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/134 reads (37%) | PolyPhen benign (0.022); catalogued as COSV100592520, COSV100619238; called by muse, mutect2, varscan2
- TTN | c.19687G>T p.A6563S (on ENST00000591111; = p.A5636S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | PolyPhen benign (0.001); catalogued as COSV59873924, COSV59891082; called by muse, mutect2, varscan2
- TUT1 | c.1354A>T p.T452S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV99545431; called by muse, mutect2, varscan2
- UBAC2 | c.416T>C p.V139A (on ENST00000403766 / NM_001144072.2; = p.V104A on NM_177967.4) | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV100854322; called by muse, mutect2, varscan2
- UBN2 | c.565G>T p.G189W | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99944151; called by muse, mutect2, varscan2
- UBQLN4 | c.763C>G p.P255A | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100849353; called by muse, mutect2, varscan2
- UNC93B1 | c.701G>T p.C234F | Missense Mutation (SNP) | VAF 273/394 reads (69%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99916440; called by muse, mutect2, varscan2
- UROC1 | c.170A>T p.Q57L | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV99331744; called by muse, mutect2, varscan2
- USP32 | c.3482A>G p.Q1161R | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.575); catalogued as rs760275237, COSV100342285; called by muse, mutect2, varscan2
- USP43 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99556821; called by muse, mutect2, varscan2
- VCX | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.427); catalogued as COSV100406328; called by muse, varscan2
- VDAC3 | c.701C>G p.S234C | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV99195127; called by muse, mutect2, varscan2
- VPS13B | c.8224G>A p.E2742K | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV62140808; called by muse, mutect2, varscan2
- VPS13D | c.9437G>T p.C3146F | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); catalogued as COSV50621385; called by muse, varscan2
- VWA3B | c.2083C>T p.Q695* | Nonsense Mutation (SNP) | VAF 24/108 reads (22%) | catalogued as rs1270769704, COSV101346072; called by muse, mutect2, varscan2
- WDR33 | c.2333G>T p.G778V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.514); catalogued as COSV100460306; called by muse, mutect2, varscan2
- WNT11 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100490367; called by muse, mutect2, varscan2
- XCL2 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773306206, COSV100892259; called by muse, mutect2, varscan2
- XIRP2 | c.1902G>T p.K634N (on ENST00000628543; = p.K809N on NM_152381.6) | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV99744629; called by muse, mutect2, varscan2
- XPO6 | c.3115C>T p.H1039Y | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100485038; called by muse, mutect2, varscan2
- XRN1 | c.3588T>A p.H1196Q | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99378339; called by muse, mutect2, varscan2
- YTHDF3 | c.1673C>T p.S558L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101572401; called by muse, mutect2, varscan2
- ZCCHC2 | c.2964C>A p.Y988* | Nonsense Mutation (SNP) | VAF 38/80 reads (48%) | catalogued as COSV99502520; called by muse, mutect2, varscan2
- ZDHHC1 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV52083569, COSV99339512; called by muse, mutect2, varscan2
- ZEB1 | c.1052T>A p.V351E | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100314613; called by muse, mutect2, varscan2
- ZEB2 | c.1784C>G p.P595R | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CD161838, COSV100356382; called by muse, mutect2, varscan2
- ZFHX4 | c.8651A>G p.Q2884R | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.754); catalogued as COSV99264554; called by muse, mutect2, varscan2
- ZFX | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 88/144 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as COSV100457830; called by muse, mutect2, varscan2
- ZFYVE28 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as COSV99343172; called by muse, mutect2, varscan2
- ZIK1 | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100277550; called by muse, mutect2, varscan2
- ZNF17 | c.1283C>A p.T428K | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0.055); catalogued as COSV100300088; called by muse, mutect2, varscan2
- ZNF18 | c.578-2A>T p.X193_splice | Splice Site (SNP) | VAF 14/21 reads (67%) | catalogued as COSV100503130; called by muse, mutect2, varscan2
- ZNF184 | c.755G>T p.C252F | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99279781; called by muse, mutect2, varscan2
- ZNF217 | c.1034C>A p.S345* | Nonsense Mutation (SNP) | VAF 60/163 reads (37%) | catalogued as COSV100184570; called by muse, mutect2, varscan2
- ZNF239 | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as COSV100021843; called by muse, mutect2, varscan2
- ZNF254 | c.1508C>G p.S503* | Nonsense Mutation (SNP) | VAF 16/89 reads (18%) | catalogued as rs753170366, COSV100741694; called by muse, mutect2, varscan2
- ZNF311 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs752241852, COSV101014174, COSV65852845; called by muse, mutect2, varscan2
- ZNF311 | c.37C>G p.P13A | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as COSV101014176; called by muse, mutect2, varscan2
- ZNF33B | c.809C>G p.S270* | Nonsense Mutation (SNP) | VAF 19/129 reads (15%) | catalogued as COSV100847718; called by muse, mutect2, varscan2
- ZNF346 | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs777616975, COSV99993241; called by muse, mutect2, varscan2
- ZNF418 | c.1652C>T p.S551F | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV101268952, COSV68675988; called by muse, mutect2, varscan2
- ZNF420 | c.1878G>C p.Q626H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.269); catalogued as COSV100421416; called by muse, mutect2, varscan2
- ZNF454 | c.548G>C p.C183S | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs773117070, COSV100195083; called by muse, mutect2, varscan2
- ZNF516 | c.736G>T p.G246W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101487311, COSV71587115; called by muse, mutect2, varscan2
- ZNF518A | c.2414C>A p.P805Q | Missense Mutation (SNP) | VAF 80/107 reads (75%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV100283593, COSV60150610; called by muse, mutect2, varscan2
- ZNF549 | c.764C>G p.S255C (on ENST00000376233 / NM_001199295.2; = p.S242C on NM_153263.2) | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.45); catalogued as COSV99558645; called by muse, mutect2, varscan2
- ZNF567 | c.410A>C p.H137P (on ENST00000536254 / NM_001322913.1; = p.H106P on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV100658859; called by muse, mutect2, varscan2
- ZNF567 | c.1585G>T p.G529W (on ENST00000536254 / NM_001322913.1; = p.G498W on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100658860; called by muse, mutect2, varscan2
- ZNF581 | c.582G>C p.W194C | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as COSV99553174; called by muse, mutect2, varscan2
- ZNF750 | c.957C>A p.Y319* | Nonsense Mutation (SNP) | VAF 111/249 reads (45%) | catalogued as COSV99489823; called by muse, mutect2, varscan2
- ZNF8 | c.1417G>T p.G473W | Missense Mutation (SNP) | VAF 105/385 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99544412; called by muse, mutect2, varscan2
- ZNF804B | c.3856C>A p.L1286M | Missense Mutation (SNP) | VAF 144/327 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV60817313, COSV60862601; called by muse, varscan2
- ZNF804B | c.3962A>T p.Q1321L | Missense Mutation (SNP) | VAF 104/261 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100304572; called by muse, varscan2
- ZNF827 | c.2978G>T p.G993V | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.04); catalogued as rs1182367774, COSV101061487; called by muse, mutect2, varscan2
- ZNF827 | c.2977G>T p.G993W | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as COSV101061488, COSV65226368; called by muse, mutect2, varscan2
- ZNF831 | c.2773G>T p.A925S | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.086); catalogued as rs761912645, COSV100926111; called by muse, mutect2, varscan2
- ZSCAN2 | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as COSV100491435, COSV100491507; called by muse, mutect2, varscan2
- ZSCAN29 | c.2177G>T p.R726I | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101212218; called by muse, mutect2, varscan2
- ZYG11B | c.2128C>T p.H710Y | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.213); catalogued as COSV99597561; called by muse, mutect2, varscan2
- AC024940.1 | n.2736-1_2736insC | Splice Region (INS) | VAF 44/137 reads (32%) | called by muse*, mutect2, varscan2*
- ADCY5 | c.1270del p.E424Rfs*21 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | called by mutect2, pindel, varscan2
- ADGRB2 | c.3035del p.C1012Sfs*79 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, pindel, varscan2
- ANO5 | c.2534del p.L845* | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | called by mutect2, pindel, varscan2
- ANO5 | c.2531T>A p.F844Y | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CCDC114 | c.1895del p.G632Efs*115 | Frame Shift Del (DEL) | VAF 50/202 reads (25%) | called by mutect2, pindel, varscan2
- COL21A1 | c.1517del p.G506Efs*74 | Frame Shift Del (DEL) | VAF 10/91 reads (11%) | called by mutect2, pindel, varscan2
- CYFIP2 | c.2712dup p.A905Cfs*86 (on ENST00000616178 / NM_001291722.2; = p.A880Cfs*86 on NM_014376.4) | Frame Shift Ins (INS) | VAF 29/63 reads (46%) | called by mutect2, varscan2
- CYFIP2 | c.2713delinsTC p.A905Sfs*86 (on ENST00000616178 / NM_001291722.2; = p.A880Sfs*86 on NM_014376.4) | Frame Shift Ins (INS) | VAF 28/83 reads (34%) | called by mutect2*, pindel, varscan2*
- DCUN1D4 | c.192G>T p.R64S | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- IGKV1D-8 | c.167C>G p.A56G | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- IGKV2D-30 | c.272G>C p.G91A | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- KRT16 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.038); called by muse, mutect2
- MBL2 | c.195del p.L66Sfs*75 | Frame Shift Del (DEL) | VAF 56/144 reads (39%) | called by mutect2, pindel, varscan2
- MPDZ | c.4523dup p.S1510Efs*25 | Frame Shift Ins (INS) | VAF 16/70 reads (23%) | called by mutect2, pindel, varscan2
- MRC1 | c.3272C>A p.P1091Q | Missense Mutation (SNP) | VAF 97/471 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- MROH5 | c.3169C>G p.R1057G | Missense Mutation (SNP) | VAF 2/12 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- NLRP14 | c.48del p.L17Cfs*6 | Frame Shift Del (DEL) | VAF 21/122 reads (17%) | called by mutect2, pindel, varscan2
- OR10S1 | c.964_965del p.E323Vfs*? | Frame Shift Del (DEL) | VAF 8/69 reads (12%) | called by mutect2, pindel, varscan2
- OR11H12 | c.251del p.L84* | Frame Shift Del (DEL) | VAF 20/112 reads (18%) | called by mutect2, varscan2
- OR13G1 | c.153del p.L52Cfs*10 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | called by mutect2, pindel, varscan2
- OR5M1 | c.704del p.H235Pfs*11 | Frame Shift Del (DEL) | VAF 25/147 reads (17%) | called by mutect2, pindel, varscan2
- PIMREG | c.96_97dup p.V33Gfs*9 | Frame Shift Ins (INS) | VAF 13/31 reads (42%) | called by mutect2, pindel, varscan2
- PRAMEF18 | c.285C>T p.P95= | Splice Region (SNP) | VAF 38/452 reads (8%) | called by muse, mutect2
- RIMS2 | c.1947_1982del p.Q650_I661del (on ENST00000666250 / NM_001348490.2; = p.Q458_I469del on NM_014677.5 and 7 other RefSeq transcripts) | In Frame Del (DEL) | VAF 30/122 reads (25%) | called by mutect2, pindel
- TG | c.7222_7229dup p.V2411Gfs*5 | Frame Shift Ins (INS) | VAF 23/95 reads (24%) | called by mutect2, varscan2
- TMEM176A | c.195dup p.I66Dfs*73 | Frame Shift Ins (INS) | VAF 34/98 reads (35%) | called by mutect2, pindel, varscan2
- TRBC2 | c.427C>A p.L143M | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TTC14 | c.962del p.G321Dfs*7 | Frame Shift Del (DEL) | VAF 64/235 reads (27%) | called by mutect2, pindel, varscan2
- USH1C | c.37-3del | Splice Region (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel, varscan2
- USH2A | c.7189del p.V2397Cfs*16 | Frame Shift Del (DEL) | VAF 38/121 reads (31%) | called by mutect2, pindel, varscan2
- VPS13D | c.10660del p.D3554Tfs*11 | Frame Shift Del (DEL) | VAF 77/217 reads (35%) | called by mutect2, pindel, varscan2
- AADAT | c.21C>T p.I7= | Silent (SNP) | VAF 34/138 reads (25%) | catalogued as rs781349483, COSV100528661; called by muse, mutect2, varscan2
- ABCA4 | c.3942C>A p.P1314= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as COSV100933165; called by muse, mutect2, varscan2
- ABCG4 | c.1185G>T p.R395= | Silent (SNP) | VAF 41/166 reads (25%) | catalogued as COSV100266864; called by muse, mutect2, varscan2
- ACAT2 | c.1161G>A p.G387= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV100364963; called by muse, mutect2, varscan2
- ACTL9 | c.528C>T p.Y176= | Silent (SNP) | VAF 43/81 reads (53%) | catalogued as COSV100185328; called by muse, mutect2, varscan2
- ADAM23 | c.474C>T p.F158= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs141683172; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADH1A | c.906C>G p.L302= | Silent (SNP) | VAF 46/195 reads (24%) | catalogued as COSV99265838, COSV99265856; called by muse, mutect2, varscan2
- AGA | c.759A>C p.A253= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV99219576; called by muse, mutect2, varscan2
- AKAP9 | c.5301C>T p.L1767= (on ENST00000359028; = p.L1735= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/200 reads (17%) | catalogued as rs1335976334, COSV100662583; called by muse, mutect2, varscan2
- ANGPTL1 | c.570T>A p.S190= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV99328251; called by muse, mutect2, varscan2
- ANKFN1 | c.1186C>A p.R396= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs1354081314, COSV100593762; called by muse, mutect2, varscan2
- ANO7 | c.1776C>T p.F592= (on ENST00000274979; = p.F538= on NM_001370694.2) | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV99238834; called by muse, mutect2, varscan2
- ARID4A | c.2607A>T p.I869= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV62162301; called by muse, mutect2, varscan2
- ASB15 | c.1107T>C p.L369= | Silent (SNP) | VAF 69/151 reads (46%) | catalogued as COSV99306740; called by muse, mutect2, varscan2
- ASB4 | c.633C>A p.P211= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV100367214; called by muse, mutect2, varscan2
- ASIC3 | c.894C>G p.P298= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV52525419, COSV99877108; called by muse, mutect2, varscan2
- ASPH | c.204A>G p.T68= | Silent (SNP) | VAF 41/165 reads (25%) | catalogued as COSV100727649; called by muse, mutect2, varscan2
- ATG2A | c.4548G>A p.L1516= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs200937104, COSV101034551; called by muse, varscan2
- BOD1L1 | c.9030G>A p.E3010= | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as COSV99239765; called by muse, mutect2, varscan2
- C12orf71 | c.147T>C p.P49= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as rs781425384, COSV101460532; called by muse, mutect2, varscan2
- C6 | c.2643C>G p.V881= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV54706088; called by muse, mutect2, varscan2
- CACNA1S | c.3138C>T p.I1046= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV62941764; called by muse, mutect2, varscan2
- CADM2 | c.627C>G p.S209= (on ENST00000407528 / NM_001167674.2; = p.S211= on NM_153184.4) | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV101057207; called by muse, mutect2, varscan2
- CAPN13 | c.1351C>T p.L451= | Silent (SNP) | VAF 46/242 reads (19%) | catalogued as COSV99700440; called by muse, varscan2
- CATSPER1 | c.1593C>A p.T531= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV100376063; called by muse, mutect2, varscan2
- CCDC116 | c.903G>A p.L301= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as rs772105775, COSV99488961; called by muse, mutect2
- CHRNA7 | c.630T>C p.Y210= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as COSV100181408; called by muse, mutect2, varscan2
- CLASP2 | c.1434G>A p.Q478= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100223742; called by muse, mutect2, varscan2
- CNTNAP2 | c.378C>G p.P126= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100667967; called by muse, mutect2, varscan2
- CNTNAP5 | c.2487A>T p.L829= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as COSV101443755; called by muse, mutect2, varscan2
- COL19A1 | c.336C>A p.A112= | Silent (SNP) | VAF 49/120 reads (41%) | catalogued as COSV100506689; called by muse, mutect2, varscan2
- COL6A3 | c.3198C>A p.R1066= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV99799428; called by muse, mutect2, varscan2
- CRX | c.615C>A p.P205= | Silent (SNP) | VAF 68/206 reads (33%) | catalogued as CD043404, COSV99704563; called by muse, mutect2, varscan2
- CSMD2 | c.2448G>T p.A816= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV53913547; called by muse, mutect2, varscan2
- CSMD3 | c.5139T>A p.L1713= (on ENST00000297405 / NM_001363185.1; = p.L1609= on NM_052900.3) | Silent (SNP) | VAF 48/160 reads (30%) | catalogued as COSV99838543; called by muse, mutect2, varscan2
- DACT1 | c.1086G>A p.V362= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100241949; called by muse, mutect2, varscan2
- DCAF4 | c.294G>A p.Q98= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as COSV100611090; called by muse, mutect2, varscan2
- DDX60L | c.3804T>A p.L1268= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99487848; called by muse, mutect2, varscan2
- DENND2A | c.2898G>T p.R966= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as rs1212220136, COSV99326395; called by muse, mutect2, varscan2
- DHRS7C | c.598C>T p.L200= (on ENST00000330255 / NM_001220493.2; = p.L199= on NM_001105571.3) | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100364800; called by muse, mutect2, varscan2
- DHX9 | c.750G>T p.L250= | Silent (SNP) | VAF 39/111 reads (35%) | catalogued as COSV100841464; called by muse, mutect2, varscan2
- DHX9 | c.3195G>A p.L1065= | Silent (SNP) | VAF 22/133 reads (17%) | catalogued as rs1319658962, COSV100841465; called by muse, mutect2, varscan2
- DMBT1 | c.810G>T p.V270= | Silent (SNP) | VAF 175/393 reads (45%) | catalogued as rs747952382, COSV100353405, COSV57533788; called by muse, mutect2, varscan2
- DNAI2 | c.63G>A p.S21= | Silent (SNP) | VAF 48/148 reads (32%) | catalogued as rs747888220, COSV56759929; called by muse, mutect2, varscan2
- DOCK2 | c.1920G>T p.V640= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as COSV99913480; called by muse, mutect2, varscan2
- DST | c.14934G>T p.L4978= (on ENST00000361203 / NM_001374722.1; = p.L2566= on NM_015548.5) | Silent (SNP) | VAF 61/334 reads (18%) | catalogued as COSV99757741; called by muse, mutect2, varscan2
- ELFN2 | c.150G>C p.P50= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV101297580, COSV68745151; called by muse, mutect2, varscan2
- EML5 | c.3768A>C p.L1256= | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as COSV100715870; called by muse, mutect2, varscan2
- FBLN7 | c.1173G>T p.R391= | Silent (SNP) | VAF 51/146 reads (35%) | catalogued as rs1307870689, COSV99734916; called by muse, mutect2, varscan2
- FBXL13 | c.1182C>T p.F394= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV100501812; called by muse, mutect2, varscan2
- FGD5 | c.2361C>A p.I787= | Silent (SNP) | VAF 108/225 reads (48%) | catalogued as COSV99548531; called by muse, varscan2
- FOXA1 | c.696A>T p.A232= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99163555; called by mutect2, varscan2
- FRYL | c.8400A>T p.L2800= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99977344; called by muse, mutect2, varscan2
- FXR1 | c.696G>T p.L232= | Silent (SNP) | VAF 87/151 reads (58%) | catalogued as COSV99976482; called by muse, mutect2, varscan2
- GABBR1 | c.432C>T p.I144= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV100589834; called by muse, mutect2, varscan2
- GLRA3 | c.723G>T p.T241= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs116414284, COSV99927747; called by muse, mutect2, varscan2
- GPRIN3 | c.1086C>T p.C362= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as rs1485299076, COSV100310823; called by muse, mutect2, varscan2
- GRM3 | c.759C>T p.R253= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV100862665; called by muse, mutect2, varscan2
- H2BC14 | c.135G>T p.V45= | Silent (SNP) | VAF 38/260 reads (15%) | catalogued as rs773382699, COSV100297635; called by muse, mutect2, varscan2
- H3C8 | c.123C>A p.R41= | Silent (SNP) | VAF 39/117 reads (33%) | catalogued as COSV100010215; called by muse, mutect2, varscan2
- HMCN1 | c.333T>C p.Y111= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV99631383; called by muse, mutect2
- HOXD3 | c.840G>T p.V280= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV99980276; called by muse, mutect2, varscan2
- IGHG2 | c.693C>A p.P231= | Silent (SNP) | VAF 94/311 reads (30%) | catalogued as rs1470315294; called by muse, varscan2
- IGHG3 | c.267C>T p.P89= | Silent (SNP) | VAF 25/134 reads (19%) | catalogued as rs759756948; called by muse, mutect2, varscan2
- IGHV3-48 | c.234C>T p.Y78= | Silent (SNP) | VAF 71/279 reads (25%) | catalogued as rs782250245; called by muse, mutect2, varscan2
- JADE2 | c.1014C>A p.A338= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as COSV99253374; called by muse, mutect2, varscan2
- KCNC2 | c.1047G>C p.V349= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV100129189; called by muse, mutect2, varscan2
- KCNH6 | c.810G>T p.T270= | Silent (SNP) | VAF 75/235 reads (32%) | catalogued as COSV100121140; called by muse, mutect2, varscan2
- KCNJ3 | c.453C>T p.I151= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV99715423, COSV99716070; called by muse, mutect2, varscan2
- KDM7A | c.2694A>C p.A898= | Silent (SNP) | VAF 27/186 reads (15%) | catalogued as COSV99134687; called by muse, mutect2, varscan2
- KIF13B | c.3945G>T p.V1315= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV101576044; called by muse, varscan2
- KLK15 | c.465G>C p.G155= | Silent (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2
- LAIR2 | c.213T>C p.S71= | Silent (SNP) | VAF 58/166 reads (35%) | catalogued as COSV100003335; called by muse, mutect2, varscan2
- LRP5 | c.1782G>A p.V594= | Silent (SNP) | VAF 11/198 reads (6%) | catalogued as COSV99592285; called by muse, mutect2
- LRP6 | c.732A>T p.T244= | Silent (SNP) | VAF 52/183 reads (28%) | catalogued as COSV99743707; called by muse, mutect2, varscan2
- LRRK2 | c.7477T>C p.L2493= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as COSV100110651; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2925C>T p.A975= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99169315; called by muse, mutect2, varscan2
- MC4R | c.900G>A p.L300= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV100236054; called by muse, mutect2, varscan2
- MEI1 | c.3018T>A p.T1006= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV100300108; called by muse, mutect2, varscan2
- MESP2 | c.399C>G p.G133= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs1314221278, COSV100510788; called by muse, mutect2
- MET | c.1299A>G p.Q433= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as rs201326561, COSV100577281; called by muse, mutect2, varscan2
- MIB2 | c.2157G>C p.L719= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs1369099352, COSV100598964; called by muse, mutect2, varscan2
- MOS | c.462C>T p.A154= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as COSV61336649; called by muse, mutect2, varscan2
- MROH5 | c.3168C>A p.V1056= | Silent (SNP) | VAF 2/12 reads (17%) | called by muse, mutect2
- MTUS2 | c.9C>G p.V3= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV101462290; called by muse, mutect2, varscan2
- MUC16 | c.26220C>T p.V8740= | Silent (SNP) | VAF 45/87 reads (52%) | catalogued as COSV101199884, COSV101200341; called by muse, mutect2, varscan2
- MYBBP1A | c.2979C>T p.L993= | Silent (SNP) | VAF 55/123 reads (45%) | catalogued as COSV99626420; called by muse, mutect2, varscan2
- NLRP8 | c.2976G>C p.A992= | Silent (SNP) | VAF 54/178 reads (30%) | catalogued as COSV52583161, COSV99405537; called by muse, mutect2, varscan2
- NOC2L | c.2169G>T p.G723= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs765044159, COSV100498088; called by muse, mutect2, varscan2
- NOMO1 | c.2691G>T p.L897= | Silent (SNP) | VAF 42/210 reads (20%) | catalogued as COSV99814637; called by muse, mutect2, varscan2
- NUBP1 | c.198T>G p.V66= | Silent (SNP) | VAF 26/141 reads (18%) | catalogued as rs769531441, COSV99296848; called by muse, mutect2, varscan2
- NVL | c.2115A>T p.L705= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV99894604; called by muse, mutect2, varscan2
- NXPH2 | c.690C>A p.V230= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99740888; called by muse, mutect2, varscan2
- OLFML1 | c.118C>A p.R40= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV100252703, COSV61403141; called by muse, mutect2, varscan2
- OPRPN | c.267A>G p.P89= | Silent (SNP) | VAF 53/742 reads (7%) | catalogued as rs756999042, COSV101271095, COSV68192600; called by muse, mutect2
- OR10K2 | c.606C>A p.L202= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV100149555; called by muse, mutect2, varscan2
- OR2T2 | c.343C>T p.L115= | Silent (SNP) | VAF 26/241 reads (11%) | catalogued as COSV100737716; called by muse, mutect2, varscan2
- OR4C3 | c.612C>A p.I204= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs762955826, COSV60586546; called by muse, mutect2, varscan2
- OR4D10 | c.468C>A p.S156= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV101597018; called by muse, mutect2, varscan2
- OR51F2 | c.840T>C p.N280= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV100438085; called by muse, mutect2, varscan2
- OR5H2 | c.363A>G p.A121= | Silent (SNP) | VAF 79/192 reads (41%) | catalogued as COSV100788763; called by muse, mutect2, varscan2
- OR8B12 | c.777C>G p.L259= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100172822; called by muse, mutect2, varscan2
- OR9G1 | c.357T>C p.Y119= | Silent (SNP) | VAF 26/176 reads (15%) | catalogued as rs749449601, COSV100380467; called by muse, mutect2
- PABPC3 | c.1353T>A p.G451= | Silent (SNP) | VAF 84/170 reads (49%) | catalogued as COSV99879657; called by muse, mutect2, varscan2
- PACRG | c.393C>A p.I131= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs892480180, COSV61304396; called by muse, mutect2, varscan2
- PAPPA2 | c.1716C>T p.V572= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV100866860, COSV62777448; called by muse, mutect2
- PAX1 | c.639G>C p.S213= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as COSV101270331; called by muse, mutect2, varscan2
- PCBP1 | c.453G>A p.V151= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV100340172; called by muse, varscan2
- PCDH10 | c.2514G>A p.K838= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99993938; called by muse, mutect2, varscan2
- PCDHGA2 | c.1350C>A p.P450= | Silent (SNP) | VAF 51/109 reads (47%) | catalogued as COSV53920855; called by muse, mutect2, varscan2
- PDE3A | c.2607C>T p.H869= | Silent (SNP) | VAF 41/154 reads (27%) | catalogued as COSV100762368; called by muse, mutect2, varscan2
- PDE4DIP | c.4146C>G p.L1382= | Silent (SNP) | VAF 30/192 reads (16%) | catalogued as rs1553593548, COSV100520166; called by mutect2, varscan2
- PLCB3 | c.924G>T p.L308= | Silent (SNP) | VAF 47/105 reads (45%) | catalogued as COSV99657536; called by muse, mutect2, varscan2
- PPFIA2 | c.2223C>A p.V741= | Silent (SNP) | VAF 48/123 reads (39%) | catalogued as COSV100334275, COSV61043600; called by muse, mutect2, varscan2
- PRAMEF20 | c.951G>T p.P317= | Silent (SNP) | VAF 103/565 reads (18%) | called by muse, mutect2, varscan2
- PRKD1 | c.1584G>T p.V528= | Silent (SNP) | VAF 27/152 reads (18%) | catalogued as COSV100120828; called by muse, mutect2, varscan2
- PSG1 | c.195C>T p.Y65= | Silent (SNP) | VAF 61/501 reads (12%) | catalogued as rs1388245996, COSV99740537; called by muse, mutect2, varscan2
- PTCHD4 | c.2391G>C p.L797= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV100261185; called by muse, mutect2, varscan2
- REG3A | c.87C>A p.P29= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV59408691; called by muse, mutect2, varscan2
- REM1 | c.318G>A p.R106= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV52429406; called by muse, mutect2, varscan2
- RNF10 | c.1281C>T p.F427= | Silent (SNP) | VAF 59/135 reads (44%) | catalogued as rs745831090, COSV100378773; called by muse, mutect2, varscan2
- SATB1 | c.138G>T p.G46= | Silent (SNP) | VAF 67/147 reads (46%) | catalogued as COSV100113296; called by muse, mutect2, varscan2
- SCEL | c.1584C>T p.D528= (on ENST00000349847 / NM_144777.3; = p.D508= on NM_003843.4) | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs1436875001, COSV100583036; called by muse, mutect2, varscan2
- SLC30A2 | c.663G>T p.L221= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100958578; called by muse, mutect2, varscan2
- SMG1 | c.5331G>T p.V1777= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV101246355; called by muse, mutect2, varscan2
- SNAP47 | c.444G>A p.L148= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as COSV100248290; called by muse, mutect2, varscan2
- SYNE1 | c.23292A>G p.L7764= (on ENST00000367255 / NM_182961.4; = p.L7693= on NM_033071.3) | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as COSV99569917; called by muse, mutect2, varscan2
- SYNE3 | c.2175G>C p.V725= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV100516191; called by muse, mutect2, varscan2
- TALDO1 | c.378C>T p.I126= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as rs553335941, COSV59798510; called by muse, mutect2, varscan2
- TATDN2 | c.285G>T p.G95= | Silent (SNP) | VAF 83/211 reads (39%) | catalogued as COSV99813613; called by muse, mutect2, varscan2
- TCHH | c.3720T>A p.V1240= | Silent (SNP) | VAF 44/132 reads (33%) | catalogued as COSV100915233; called by muse, mutect2, varscan2
- TCHHL1 | c.2160G>A p.L720= | Silent (SNP) | VAF 38/214 reads (18%) | catalogued as COSV100916559; called by muse, mutect2, varscan2
- TESC | c.153G>A p.P51= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs373565239; called by muse, mutect2, varscan2
- THAP4 | c.681G>T p.G227= | Silent (SNP) | VAF 21/138 reads (15%) | catalogued as COSV101126040; called by muse, mutect2, varscan2
- TLR4 | c.2442C>A p.A814= (on ENST00000355622 / NM_138554.5; = p.A774= on NM_003266.4) | Silent (SNP) | VAF 48/117 reads (41%) | catalogued as COSV100842805, COSV62922449; called by muse, mutect2, varscan2
- TNFRSF19 | c.741G>A p.P247= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs766006684, COSV50311774, COSV99947487; called by muse, mutect2, varscan2
- TOGARAM1 | c.5023C>A p.R1675= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as COSV63893374, COSV99053562; called by muse, mutect2, varscan2
- TRAPPC1 | c.249C>T p.V83= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100366529; called by muse, mutect2, varscan2
- TRIOBP | c.2151A>G p.Q717= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as rs1285313162, COSV100730957; called by muse, mutect2, varscan2
- TRPC3 | c.546C>A p.A182= (on ENST00000379645 / NM_001366479.2; = p.A109= on NM_003305.2) | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99312959; called by muse, mutect2, varscan2
- UBQLN3 | c.903T>C p.P301= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV100293786; called by muse, mutect2, varscan2
- WFDC13 | c.264C>T p.V88= | Silent (SNP) | VAF 31/100 reads (31%) | catalogued as COSV100225167; called by muse, mutect2, varscan2
- ZC3H7B | c.2514C>T p.I838= | Silent (SNP) | VAF 37/211 reads (18%) | catalogued as COSV100687483; called by muse, mutect2, varscan2
- ZIC1 | c.324C>T p.G108= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs768784777, COSV99292102; called by muse, mutect2, varscan2
- ZNF319 | c.1296G>A p.V432= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs1220830891, COSV99540297; called by muse, mutect2, varscan2
- ZNF385B | c.255C>A p.P85= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV101343138; called by muse, mutect2, varscan2
- ZNF521 | c.1896A>G p.G632= | Silent (SNP) | VAF 70/160 reads (44%) | catalogued as COSV100832622; called by muse, mutect2, varscan2
- ZNF92 | c.156G>T p.L52= | Silent (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- ZNF98 | c.1347T>A p.L449= | Silent (SNP) | VAF 45/80 reads (56%) | catalogued as COSV100757523; called by muse, mutect2, varscan2
- ACP4 | chr19:50798258 C>A | 3'Flank (SNP) | VAF 60/236 reads (25%) | catalogued as COSV99567754; called by muse, mutect2, varscan2
- AP000769.3 | n.41C>G | RNA (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2, varscan2
- BCAN | c.1942+17C>A | Intron (SNP) | VAF 50/128 reads (39%) | catalogued as COSV100228247; called by muse, mutect2, varscan2
- CARMIL3 | chr14:24048687 C>T | 5'Flank (SNP) | VAF 66/205 reads (32%) | called by muse, mutect2, varscan2
- CBX2 | c.288+89G>A | Intron (SNP) | VAF 16/100 reads (16%) | catalogued as rs1555830393, COSV99490927; called by muse, mutect2, varscan2
- CMSS1 | c.-2A>T | 5'UTR (SNP) | VAF 5/38 reads (13%) | catalogued as COSV101375601; called by muse, mutect2, varscan2
- DDX41 | c.*946C>A | 3'UTR (SNP) | VAF 21/44 reads (48%) | catalogued as COSV100394408, COSV57254467; called by muse, mutect2, varscan2
- LGALS12 | c.-44G>T | 5'UTR (SNP) | VAF 11/99 reads (11%) | catalogued as COSV99737170; called by muse, mutect2, varscan2
- MCM7 | c.1848+348C>A | Intron (SNP) | VAF 6/36 reads (17%) | catalogued as rs779705683, COSV100385021, COSV57996228; called by muse, mutect2, varscan2
- MIR527 | n.14C>G | RNA (SNP) | VAF 73/288 reads (25%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.400+6902C>G | Intron (SNP) | VAF 12/190 reads (6%) | catalogued as COSV100093278; called by muse, mutect2
- PARGP1 | n.1530G>T | RNA (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- RGS6 | c.1368+3789A>T | Intron (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100666495; called by muse, mutect2, varscan2
- RNA5-8SP2 | n.119G>C | RNA (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- RNF185 | c.-1G>C | 5'UTR (SNP) | VAF 50/190 reads (26%) | catalogued as rs753229411, COSV99839781; called by muse, mutect2, varscan2
- SNORD116-11 | n.23G>T | RNA (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2, varscan2
- TTN | c.10361-4684G>T | Intron (SNP) | VAF 24/119 reads (20%) | catalogued as COSV100619239; called by muse, mutect2, varscan2
- TUBB7P | n.1074C>A | RNA (SNP) | VAF 36/145 reads (25%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23165G>T | Intron (SNP) | VAF 52/135 reads (39%) | catalogued as COSV100530443; called by muse, mutect2, varscan2
- VMP1 | c.*1356G>T | 3'UTR (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
